Gene-level copy-number profile of tumor specimen HCM-STAN-0627-C34-01A from HCMI case HCM-STAN-0627-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 59.5 years (21,727 days).
Specimen HCM-STAN-0627-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c0304a2-1590-4478-b4aa-1b581ade5f80.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0627-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/b5bd870d-3b9d-439a-96b0-e958dfc909f8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 226; copy number 2: 13,253; copy number 3: 2,389; copy number 4: 29,832; copy number 5: 3,007; copy number 6: 5,890; copy number 7: 2; copy number 8: 1,713; copy number 9: 353; copy number 10: 677; copy number 11: 5; copy number 12: 158; copy number 13: 16; copy number 14: 145; copy number 15: 50; copy number 16: 245; copy number 17: 13; copy number 18: 188; copy number 19: 40; copy number 20: 16; copy number 21: 2; copy number 27: 67; copy number 28: 30; copy number 29: 12; copy number 40: 62; copy number 45: 2; copy number 50: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,199,973, 1 gene (within-gene range 0–2): AC105233.4.
- chr8:8,154,308–8,226,614, 3 genes: ENPP7P1, FAM85B, AC068020.1.
- chr11:4,278,705–4,279,192, 1 gene: SSU72P6.
- chr11:4,329,865–4,330,449, 1 gene: SSU72P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,082 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:47,403,067–49,451,896, 34 genes, copy number 10: MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P.
- chr2:142,131,178–142,137,830, 1 gene, copy number 9 (within-gene range 6–9): AC078882.1.
- chr7:82,589,848–102,283,958, 364 genes, copy number 12–21 (within-gene range 8–21) (broad region; genes not listed).
- chr7:111,726,110–112,206,407, 5 genes, copy number 13: DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1.
- chr8:9,136,255–11,368,452, 61 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).
- chr8:34,174,886–34,346,731, 4 genes, copy number 9: AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr9:20,658,309–21,031,640, 5 genes, copy number 11: FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4.
- chr11:68,707,440–78,574,874, 323 genes, copy number 18–45 (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 10–50 (broad region; genes not listed).
- chr16:46,469,341–47,464,149, 31 genes, copy number 9 (within-gene range 6–9): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2, AC018845.3, AC018845.1, AC018845.2, NETO2, ITFG1-AS1, RPL23AP72, ITFG1, AC007494.2, AC007494.3, AC007494.1, AC007533.1, Y_RNA.
- chr21:12,999,676–18,267,373, 107 genes, copy number 9–18 (broad region; genes not listed).
- chr22:21,628,089–25,252,602, 262 genes, copy number 9 (broad region; genes not listed).
- chr22:25,561,117–27,460,060, 54 genes, copy number 9: AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.1.

Autosomal genes at a single copy (total copy number 1): 226. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
